Somatic mutation profile of tumor specimen TCGA-5P-A9K8-01A (aliquot TCGA-5P-A9K8-01A-11D-A42J-10) from TCGA case TCGA-5P-A9K8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 51.7 years (18,880 days).
Specimen TCGA-5P-A9K8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc94718b-f635-48cf-8bce-105cd9a1d3e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9K8-10A (Blood Derived Normal), aliquot TCGA-5P-A9K8-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6e871e8-ac9e-4907-994a-3228e056747a

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.7915C>T p.R2639* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as rs375053470, CM020273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC023055.1 | c.1429A>G p.I477V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.084); catalogued as rs138765992; called by mutect2, varscan2
- CCDC57 | c.2228C>A p.A743D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV100492625; called by muse, mutect2
- DEFB110 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100953802; called by muse, mutect2, varscan2
- H2BC8 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as COSV55126191, COSV55126595; called by muse, mutect2, varscan2
- IL32 | c.627C>A p.F209L (on ENST00000396890 / NM_001308078.4; = p.F163L on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99145549; called by muse, mutect2
- MTR | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100856241; called by muse, mutect2, varscan2
- RALGAPB | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs376931767; called by muse, mutect2, varscan2
- SUCO | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs983156957, COSV99743437; called by muse, mutect2, varscan2
- TEX11 | c.154G>A p.D52N (on ENST00000344304; = p.D37N on NM_031276.3) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as rs1326402590, COSV100722093; called by muse, mutect2, varscan2
- WDR59 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100049607; called by muse, mutect2
- ZNF521 | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV100833020; called by muse, mutect2
- RASSF10 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- TXNIP | c.499_502del p.K167Ffs*63 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | called by pindel, varscan2
- ANGPT1 | c.510C>A p.T170= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52439997, COSV52446942; called by muse, mutect2, varscan2
- CCT8L2 | c.465G>A p.L155= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100742973; called by muse, mutect2
- MDGA2 | c.1500C>T p.I500= (on ENST00000399232 / NM_001113498.2; = p.I202= on NM_182830.4) | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as rs137900737; called by muse, mutect2, varscan2
- NAV3 | c.4083G>A p.P1361= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs796840739, COSV57088121; called by muse, mutect2, varscan2
- PANX2 | c.351G>A p.S117= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV99348576; called by muse, mutect2, varscan2
- PNLDC1 | c.1167C>T p.D389= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs146349877; called by muse, mutect2, varscan2
- TLR3 | c.2714A>G p.*905= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as COSV99711134; called by muse, mutect2
